EXCEPTIONAL_RESPONDERS case ER-AD3D — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4a298591-59e6-4179-a3b6-a824a2fa380f

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Classification of tumor: metastasis; Age at diagnosis: 53.6 years (19,582 days); Year of diagnosis: 2012; AJCC clinical stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,281 days (3.5 years); Days to best overall response: 134 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Bevacizumab + Cisplatin + Pemetrexed; Days to treatment start: 84 days; Days to treatment end: 352 days.

Follow-up (1 entry)
- Days to follow up: 1,281 days (3.5 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,281 days (3.5 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AD3D-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-AD3D-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 4; Percent necrosis: 3; Percent stromal cells: 23; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 8.
